CPTAC case C3L-03624 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/89f328d4-8275-4b15-98aa-a487a9b970c2

Demographics
Sex at birth: female; Year of birth: 1948; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 69.6 years (25,430 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 1,805 days (4.9 years); Progression or recurrence: yes; Days to recurrence: 1,692 days (4.6 years); Days to last follow up: 1,805 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.8 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 20; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 455 days (1.2 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 819 days (2.2 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,183 days (3.2 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,501 days (4.1 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,805 days (4.9 years); Disease response: Progressive Disease; Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 56.8 kg; Height: 160 cm; BMI: 22.19; Comorbidities: Pancreatitis.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 22.5; Cigarettes per day: 15; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 1995; Exposure duration years: 30.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03624-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 176 mg; Time between excision and freezing: 40 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide C3L-03624-22: Section location: Head; Percent tumor nuclei: 10; Percent necrosis: 0.
- Sample C3L-03624-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
